Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7JV, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7JV-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Carcinoma, squamous cell NOS
80213
Site Hypopharynx NOS
C13.9
9/24/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Hypopharynx

1 - "Right hypopharynx biopsy":

- Moderately differentiated squamous cell carcinoma.

2 - "Left-inferior parathyroid site":

- Fragment of fibroadipose tissue uninvolved by neoplasia.

3 - "Left recurrential dissection specimen":

- Two of nine lymph nodes involved by metastatic carcinoma (2/9), without capsular involvement.

5 - "Total pharyngolaryngectomy, partial esophagectomy, left neck dissection and right radical neck dissection with total thyroidectomy":

- Moderately differentiated squamous cell carcinoma of the hypopharynx.
- Epiglottis: uninvolved by neoplasia.
- Left vocal cord: uninvolved by neoplasia.
- Right vocal cord: involved by neoplasia.
- Thyroid, cricoid and arytenoid cartilages uninvolved by neoplasia.
- Hyoid bone uninvolved by neoplasia.
- Surgical margins uninvolved by neoplasia, but right-posterior and right-lateral are exiguous (measured 1.0 mm).

- Esophagus involved by neoplasia with uninvolved surgical margins.

- Thyroid gland with follicular papillary carcinoma, histological grade 2, with uninvolved margins.

- Tumor size: 1.2 cm

- Lymphovascular invasion: not identified.

- Right neck dissection:

- Three of fifteen lymph nodes involved by metastatic carcinoma (3/15), without capsular involvement.

- Left neck dissection:

- Four lymph nodes uninvolved by metastatic carcinoma (0/4).

5 - "Hypopharynx margin":

- Uninvolved by neoplasia.

[page 2 of 2]
Addendum:
Absence of neoplasia invasion on hyoid bone.

zHPAA Discrepancy		✓

Source: NCI Genomic Data Commons file 223bd642-5bac-4c5c-9955-5be72cd35ab7 (TCGA-UF-A7JV.14508F82-2D39-47A5-858E-99F3DEE97C33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).